Somatic mutation profile of tumor specimen TARGET-40-PATUXZ-01A (aliquot TARGET-40-PATUXZ-01A-01D) from TARGET case TARGET-40-PATUXZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.4 years (6,345 days).
Specimen TARGET-40-PATUXZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a36bf9f-9e52-4a68-a55e-205b42610457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATUXZ-10A (Blood Derived Normal), aliquot TARGET-40-PATUXZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad4af434-dc1e-44e0-add5-d223246598f3

The open-access MAF lists 106 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Intron 15, 3'UTR 7, Nonsense Mutation 6, RNA 4, 5'UTR 3, Splice Region 3, Translation Start Site 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1792G>T p.V598F | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67018033; called by muse, mutect2, varscan2
- ABCG1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 283/507 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs766235564, COSV59200653; called by muse, mutect2, varscan2
- ADGRG1 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV101113413; called by muse, mutect2, varscan2
- ANK2 | c.776T>G p.V259G | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52166675; called by muse, mutect2, varscan2
- ASCC2 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs765985833; called by muse, mutect2, varscan2
- ATP4A | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 153/988 reads (15%) | catalogued as COSV52867944; called by muse, mutect2, varscan2
- ATRX | c.5399T>A p.M1800K | Missense Mutation (SNP) | VAF 181/248 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64876223; called by muse, mutect2, varscan2
- CNTN6 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 156/398 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV63164865, COSV63182098; called by muse, mutect2, varscan2
- COQ2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 132/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758103492, COSV61022177, COSV61022286; called by muse, mutect2, varscan2
- DENND5A | c.3857A>G p.D1286G | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100064139; called by muse, mutect2, varscan2
- FABP7 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 160/642 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV62956968; called by muse, mutect2, varscan2
- FRG1 | c.260-1del p.X87_splice | Splice Site (DEL) | VAF 18/44 reads (41%) | catalogued as rs1265231392; called by pindel, varscan2
- GALNT13 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs778627810, COSV101222166, COSV67218786; called by muse, mutect2, varscan2
- GK | c.1462G>A p.V488I (on ENST00000427190 / NM_001205019.2; = p.V482I on NM_000167.6) | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs768478671, COSV66732332; called by muse, mutect2, varscan2
- GSTA1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 301/472 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58014770; called by muse, mutect2, varscan2
- HHIP | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 108/706 reads (15%) | catalogued as COSV56843117; called by muse, varscan2
- MUC16 | c.4574G>T p.S1525I | Missense Mutation (SNP) | VAF 704/1302 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as rs1422185223; called by muse, mutect2, varscan2
- MYH2 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 166/1342 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs773328490; called by muse, mutect2, varscan2
- PEX11B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs375205054; called by muse, mutect2, varscan2
- PKHD1L1 | c.5986G>A p.E1996K | Missense Mutation (SNP) | VAF 462/1025 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV99058815; called by muse, mutect2, varscan2
- TNNT1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 151/338 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755856894, COSV99402995; called by muse, mutect2, varscan2
- ADGRL1 | c.1524A>G p.R508= (on ENST00000340736 / NM_001008701.3; = p.R503= on NM_014921.5) | Splice Region (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- ATP13A4 | c.3190C>A p.Q1064K | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- BAZ2B | c.4607C>G p.P1536R | Missense Mutation (SNP) | VAF 156/643 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BRINP1 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CACNA1F | c.971T>A p.F324Y | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CAMK1 | c.912+3G>T | Splice Region (SNP) | VAF 372/596 reads (62%) | called by muse, mutect2, varscan2
- CGN | c.2836C>A p.L946M | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD1L | c.2317A>G p.K773E | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- COA1 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- DMXL2 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUOX1 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP1 | c.1840G>T p.G614* | Nonsense Mutation (SNP) | VAF 34/346 reads (10%) | called by muse, varscan2
- HDLBP | c.3009+7C>A | Splice Region (SNP) | VAF 120/507 reads (24%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 117/519 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KDM5B | c.4352T>A p.L1451* | Nonsense Mutation (SNP) | VAF 203/799 reads (25%) | called by muse, mutect2, varscan2
- LAMA2 | c.5342A>G p.N1781S | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA3 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 194/533 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MFSD4A | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 21/665 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MROH2A | c.3568A>C p.M1190L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MROH2B | c.3814A>G p.T1272A | Missense Mutation (SNP) | VAF 1043/1568 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MRPL12 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 142/934 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MS4A2 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 123/483 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NNT | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 159/1368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NOX3 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOX5 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5K4 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- PROM2 | c.2281G>T p.G761* | Nonsense Mutation (SNP) | VAF 557/1068 reads (52%) | called by muse, mutect2, varscan2
- RBM5 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 82/569 reads (14%) | called by muse, mutect2, varscan2
- RNF17 | c.328T>A p.C110S | Missense Mutation (SNP) | VAF 272/325 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SEPTIN3 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH2D5 | c.259C>A p.H87N (on ENST00000444387 / NM_001103161.2; = p.H3N on NM_001103160.2) | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC28A1 | c.1129T>G p.C377G | Missense Mutation (SNP) | VAF 249/934 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- STAG2 | c.932A>G p.E311G | Missense Mutation (SNP) | VAF 163/3797 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TOM1L1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 265/351 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAJ44 | c.4A>T p.N2Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- ZBTB1 | c.987G>T p.M329I | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H7A | c.2441A>T p.E814V | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF286A | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 259/303 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- AC126283.2 | c.1314C>T p.D438= | Silent (SNP) | VAF 75/185 reads (41%) | catalogued as rs775999349, COSV67099213; called by muse, mutect2, varscan2
- AMZ1 | c.384C>T p.R128= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs772214458; called by muse, mutect2, varscan2
- ATM | c.5733T>A p.A1911= | Silent (SNP) | VAF 34/449 reads (8%) | called by muse, mutect2
- BCR | c.75G>A p.L25= | Silent (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- BEST3 | c.291T>C p.F97= | Silent (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- COL4A1 | c.2736C>A p.G912= | Silent (SNP) | VAF 79/662 reads (12%) | catalogued as COSV101010995; called by muse, mutect2, varscan2
- ENAM | c.2019A>G p.E673= | Silent (SNP) | VAF 89/331 reads (27%) | catalogued as rs937703590; called by muse, mutect2, varscan2
- GLT1D1 | c.192C>T p.L64= | Silent (SNP) | VAF 162/671 reads (24%) | catalogued as COSV99897167; called by muse, mutect2, varscan2
- KRTAP21-2 | c.54C>A p.G18= | Silent (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- MAN2B2 | c.1023C>A p.V341= | Silent (SNP) | VAF 62/229 reads (27%) | called by muse, mutect2, varscan2
- MKRN2 | c.570G>T p.G190= | Silent (SNP) | VAF 302/374 reads (81%) | called by muse, mutect2, varscan2
- OR14A2 | c.813G>T p.L271= | Silent (SNP) | VAF 112/485 reads (23%) | called by muse, varscan2
- PCDHAC1 | c.1329A>G p.P443= | Silent (SNP) | VAF 134/369 reads (36%) | called by muse, mutect2, varscan2
- RIN1 | c.1227C>G p.A409= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- SCARA3 | c.1293C>T p.L431= | Silent (SNP) | VAF 62/185 reads (34%) | called by muse, mutect2, varscan2
- SENP5 | c.1956G>A p.V652= | Silent (SNP) | VAF 172/529 reads (33%) | called by muse, mutect2, varscan2
- SLC22A24 | c.630C>A p.T210= | Silent (SNP) | VAF 57/278 reads (21%) | called by muse, mutect2, varscan2
- ABLIM3 | c.757+36C>A | Intron (SNP) | VAF 67/144 reads (47%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.2356+2099C>A | Intron (SNP) | VAF 50/168 reads (30%) | called by muse, varscan2
- ARHGEF34P | n.1351C>G | RNA (SNP) | VAF 75/651 reads (12%) | catalogued as rs1288551342; called by muse, mutect2, varscan2
- ATP1A2 | c.117+67C>T | Intron (SNP) | VAF 118/934 reads (13%) | called by muse, mutect2, varscan2
- BCR | c.2116-94T>C | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- CHP2 | c.68-24C>A | Intron (SNP) | VAF 121/285 reads (42%) | called by muse, varscan2
- CYRIA | c.*108C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- DARS1 | c.-107C>G | 5'UTR (SNP) | VAF 30/100 reads (30%) | catalogued as rs774148880; called by muse, mutect2, varscan2
- ECE2 | c.2163+38G>T | Intron (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- GET4 | c.156-1819C>T | Intron (SNP) | VAF 74/328 reads (23%) | catalogued as COSV56256439; called by muse, mutect2, varscan2
- GP6 | c.*22C>A | 3'UTR (SNP) | VAF 116/483 reads (24%) | called by muse, mutect2, varscan2
- ILF2 | chr1:153671009 G>T | 5'Flank (SNP) | VAF 203/757 reads (27%) | catalogued as rs558472881; called by muse, mutect2, varscan2
- MBL3P | n.294G>T | RNA (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- METTL27 | c.479-55G>T | Intron (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- MORN1 | c.450-85G>A | Intron (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- MSRB1 | c.204+98G>T | Intron (SNP) | VAF 20/96 reads (21%) | catalogued as rs780045430; called by muse, mutect2, varscan2
- PAFAH1B3 | c.408+11G>T | Intron (SNP) | VAF 172/818 reads (21%) | called by mutect2, varscan2
- PEG10 | c.*547dup | 3'UTR (INS) | VAF 160/679 reads (24%) | called by mutect2, pindel, varscan2
- PRKCSH | c.80-94_80-93dup | Intron (INS) | VAF 70/326 reads (21%) | called by mutect2, pindel, varscan2
- RPL7P9 | n.688G>C | RNA (SNP) | VAF 84/312 reads (27%) | called by muse, mutect2, varscan2
- RPLP0 | c.792+106T>C | Intron (SNP) | VAF 19/64 reads (30%) | called by mutect2, varscan2
- SCFD1 | c.*25T>C | 3'UTR (SNP) | VAF 52/189 reads (28%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*592C>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs1159075468; called by muse, mutect2, varscan2
- SPINT3 | c.*118A>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- UBE2N | c.277+27C>T | Intron (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.-68C>G | 5'UTR (SNP) | VAF 62/242 reads (26%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+44283C>T | Intron (SNP) | VAF 589/765 reads (77%) | called by muse, mutect2, varscan2
- ZNF117 | c.*1211G>T | 3'UTR (SNP) | VAF 22/419 reads (5%) | called by muse, mutect2
- ZNF528 | c.-97del | 5'UTR (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- ZNF658B | n.1201C>A | RNA (SNP) | VAF 336/1119 reads (30%) | called by muse, mutect2, varscan2
